National Lung Screening Trial (NLST) participant 119853 — screening results
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 63 years; Gender: male; Race: White; Cigarette smoking status at randomisation: former smoker (to be eligible, former smokers had quit within the previous 15 years); Enrolled through a Lung Screening Study (LSS) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; no CT screening exam record exists for this participant — in this public subset that is the pattern of the chest-radiography arm: every CT screen with a result has an exam record, and the subset has no trial-arm field)
- T0 (day 0): Negative screen, no significant abnormalities.
- T1 (day 399): Negative screen, no significant abnormalities.
- T2 (day 720): Negative screen, no significant abnormalities.

Follow-up
No confirmed lung cancer during the trial; Last known free of lung cancer: day 2,484.
